Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4770, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4770-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

with large left renal mass with left renal vein thrombus (negative mets work-up).

Specimens Submitted:

- 1: SP: Left kidney, distal pancreas, spleen, and left adrenal gland, radical nephrectomy, partial pancreatectomy and splenectomy
- 2: SP: Soft tissue, vena cava, biopsy
- 3: SP: Lymph nodes, para-aortic, excision
- 4: SP: Soft tissue, left psoas muscle, biopsy

DIAGNOSIS:

1. SP: Left kidney, distal pancreas, spleen, and left adrenal gland, radical nephrectomy, partial pancreatectomy and splenectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

The tumor is growing almost entirely with sarcomatoid features (sarcomatoid carcinoma).

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 15 cm.

Local Invasion (for renal cortical types):

Involves Gerota's fascia

Involves renal sinus fat

Involves renal hilar fat

Renal Vein Invasion:

Identified

Surgical Margins:

Tumor is focally present at inked resection margin.

Non-Neoplastic Kidney:

Chronic inflammation

Adrenal Gland:

Involved by tumor by direct extension

Lymph Nodes:

Free of tumor

Staging for renal cell carcinoma/oncocytoma:

pT4 Tumor invades beyond Gerota's fascia

Comment: The tumor directly extends into the adjacent segment of pancreas.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Unremarkable spleen.

2. SP: Soft tissue, vena cava, biopsy
Fragments of carcinoma are present.

3. SP: Lymph nodes, para-aortic, excision
Lymph Nodes:
Not involved
Number of nodes examined:13

4. SP: Soft tissue, left psoas muscle, biopsy
Edematous soft tissue with chronic inflammation and fibrosis.

Gross Description:

1) The specimen is received fresh, labeled "Distal pancreas, spleen, left kidney and adrenal gland. It consists of a 1.5 kg radical nephrectomy specimen measuring 24.0 x 13.0 x 11.5 cm with a 7.0 x 0.5 x 0.5 cm segment of ureter and with an attached adrenal gland, spleen and segment of distal pancreas. The adrenal gland measures 8.0 x 3.0 cm, the 116g spleen measures 11.5 x 7.0 x 3.5 cm and the distal segment of pancreas measures 7.0 x 2.0 cm. The specimen is inked black and bivalved to show a 15.0 x 12.5 x 11.0 cm well-circumscribed firm tan-white mass with central necrosis, hemorrhage and focal cystic degeneration. The mass occupies the majority of the kidney with a small portion of normal renal parenchyma identified at the lower pole of the kidney. The lesion grossly involves the renal vein and its branches but is grossly not present at the renal vein margin. The tumor pushes into the renal sinus fat and directly abuts the overlying inked resection margin. The tumor also shows direct extension into the attached adrenal gland and portion of pancreas. The spleen is grossly uninvolved by tumor and serially sections show no gross abnormalities. Photographs are taken and sections of tumor are taken for TPS. Representative sections are submitted.

Summary of Sections:

UVM – ureteral and vascular margin
VEINTUM – renal vein with tumor
TUMHILUM – tumor with hilum
TUMSINUS – tumor with renal sinus
TUMCATS – tumor with overlying capsule
TUMADJ – tumor with adjacent normal kidney
TUMADR – tumor and adrenal
TUMPAN – tumor and pancreas
NLKID – representative sections from uninvolved kidney
SPLEEN – representative sections from spleen

2) The specimen is received in formalin, labeled "Tumor from vena cava". It consists of a 1.1 x 1.0 x 0.9 cm fragment of tan-red soft tissue. The specimen is serially sectioned and submitted in its entirety.

Summary of Sections:

U - undesignated

3) The specimen is received in formalin, labeled "Para-aortic lymph nodes". It consists of a 4.5 x 2.8 x 1.8 cm fragment of hemorrhagic fibroadipose tissue with multiple staples. Multiple lymph nodes are identified measuring from 0.2 to 1.1 cm in greatest dimension. All lymph nodes are submitted.

[page 3 of 3]
Summary of Sections:

U - undesignated

4) The specimen is received in formalin, labeled "Soft tissue of left psoas muscle". It consists of two pieces of tan-red soft tissue measuring 3.7 x 2.6 x 0.3 cm and 3.7 x 1.2 x 0.3 cm. No gross abnormalities are identified. The specimen is serially sectioned and submitted in its entirety.

Summary of Sections:

U - undesignated

Summary of Sections:

Part 1: SP: Left kidney, distal pancreas, spleen, and left adrenal gland, radical nephrectomy, partial pancreatectomy and splenectomy

Block	Sect. Site	PCs
1	nlkid	1
1	spleen	1
1	tumadj	1
2	tumadr	2
7	tumcaps	7
1	tumhilum	1
2	tumpan	2
2	tumsinus	2
1	uvm	1
1	veintum	1

Part 2: SP: Soft tissue, vena cava, biopsy

Block	Sect. Site	PCs
1	u	1

Part 3: SP: Lymph nodes, para-aortic, excision

Block	Sect. Site	PCs
4	u	4

Part 4: SP: Soft tissue, left psoas muscle, biopsy

Block	Sect. Site	PCs
3	u	3

Source: NCI Genomic Data Commons file 32c9cd52-f79f-40f9-a884-19a92781084a (TCGA-BP-4770.28B3979E-7012-4F0C-9942-6C99B2CE36DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).